CCDI case PBBVCN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0de74d5d-be66-4836-b99a-6161f0a10bdf

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.5 years (6,774 days).

Biospecimens (3 samples)
- Sample 0DHY2W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY3Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY54: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
